Somatic mutation profile of tumor specimen 0DPMRS from CCDI case PBCDVZ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 4.7 years (1,726 days).
Specimen 0DPMRS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 90f0015f-d7db-413e-9414-e7043051a61e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DPMQU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a21871c7-c717-4d2c-874d-6a88cd334f6d

The open-access MAF lists 33 somatic variants for this specimen: 24 protein-altering or splice-affecting, 6 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 21, Silent 6, Intron 3, Splice Region 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CLN6 | c.407G>A p.R136H | Missense Mutation (SNP) | VAF 129/352 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs769701646, CM1512132; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS19 | c.3107G>A p.R1036H | Missense Mutation (SNP) | VAF 190/881 reads (22%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.928); catalogued as rs769134309, COSV50787858; called by muse, mutect2, varscan2
- KCNG3 | c.788C>T p.T263M | Missense Mutation (SNP) | VAF 225/725 reads (31%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs148581980; called by muse, mutect2, varscan2
- KCNH3 | c.2090G>A p.R697Q | Missense Mutation (SNP) | VAF 146/438 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs374912395; called by muse, mutect2, varscan2
- LRRC9 | c.137G>A p.R46H | Missense Mutation (SNP) | VAF 141/449 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.048); catalogued as rs562390499; called by muse, mutect2, varscan2
- MEGF8 | c.5348G>A p.R1783H (on ENST00000251268 / NM_001271938.2; = p.R1716H on NM_001410.3) | Missense Mutation (SNP) | VAF 122/401 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs183945597; called by muse, mutect2, varscan2
- MYO15A | c.5197C>T p.R1733W | Missense Mutation (SNP) | VAF 152/484 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs369755064, COSV52761330; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIK3R6 | c.1762G>T p.A588S | Missense Mutation (SNP) | VAF 163/508 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs774403746; called by muse, mutect2, varscan2
- SCN9A | c.77G>A p.R26H | Missense Mutation (SNP) | VAF 215/814 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.915); catalogued as rs111404258; called by muse, mutect2, varscan2
- STX3 | c.452G>A p.R151Q | Missense Mutation (SNP) | VAF 96/251 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55696791; called by muse, mutect2, varscan2
- TBC1D15 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 160/629 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs374857229; called by muse, mutect2, varscan2
- TBC1D24 | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 25/551 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.018); catalogued as rs1437428111; called by muse, mutect2
- ADCY4 | c.1946T>G p.L649R | Missense Mutation (SNP) | VAF 59/251 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- CDKN1C | c.599del p.P200Qfs*72 | Frame Shift Del (DEL) | VAF 40/93 reads (43%) | called by mutect2, varscan2
- FAM170A | c.648G>T p.K216N | Missense Mutation (SNP) | VAF 86/449 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- LONP1 | c.1822C>G p.L608V | Missense Mutation (SNP) | VAF 138/455 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PKHD1L1 | c.3123G>A p.Q1041= | Splice Region (SNP) | VAF 110/506 reads (22%) | called by muse, varscan2
- POLDIP2 | c.28C>G p.L10V | Missense Mutation (SNP) | VAF 46/206 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- PPM1A | c.544G>C p.V182L | Missense Mutation (SNP) | VAF 161/604 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- PXK | c.1286G>T p.R429I | Missense Mutation (SNP) | VAF 200/559 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- RASGRF1 | c.277-4A>G | Splice Region (SNP) | VAF 186/627 reads (30%) | called by muse, mutect2, varscan2
- SUCLG2 | c.509G>A p.S170N | Missense Mutation (SNP) | VAF 171/376 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.49645C>A p.P16549T (on ENST00000591111; = p.P9125T on NM_003319.4) | Missense Mutation (SNP) | VAF 189/606 reads (31%) | PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF263 | c.518A>G p.E173G | Missense Mutation (SNP) | VAF 112/254 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CCM2 | c.373A>C p.R125= | Silent (SNP) | VAF 20/591 reads (3%) | called by muse, mutect2
- CFAP100 | c.108G>A p.K36= | Silent (SNP) | VAF 132/287 reads (46%) | called by muse, mutect2, varscan2
- COL8A2 | c.1701C>G p.G567= | Silent (SNP) | VAF 48/135 reads (36%) | called by muse, mutect2, varscan2
- NFATC4 | c.1206C>G p.A402= | Silent (SNP) | VAF 133/515 reads (26%) | called by muse, mutect2, varscan2
- POLDIP2 | c.27C>A p.A9= | Silent (SNP) | VAF 48/207 reads (23%) | called by muse, mutect2, varscan2
- PSMD2 | c.309T>C p.Y103= | Silent (SNP) | VAF 56/752 reads (7%) | catalogued as rs761609354; called by muse, mutect2
- ANO3 | c.1447+3287A>G | Intron (SNP) | VAF 64/150 reads (43%) | called by muse, mutect2, varscan2
- BAX | c.474+122G>T | Intron (SNP) | VAF 110/368 reads (30%) | catalogued as rs1158033620; called by mutect2, varscan2
- GATD1 | c.356-48G>C | Intron (SNP) | VAF 22/32 reads (69%) | called by muse, mutect2
